Somatic mutation profile of tumor specimen TCGA-EY-A1GV-01A (aliquot TCGA-EY-A1GV-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 75.5 years (27,581 days).
Specimen TCGA-EY-A1GV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90c4d07d-fcde-4a8a-ac35-c27d44c96306.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GV-10A (Blood Derived Normal), aliquot TCGA-EY-A1GV-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd07aad4-6bec-4734-8c03-d732ff4d8cac

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, In Frame Del 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 14/41 reads (34%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM120849, CM134998, COSV52681833, COSV52696302, COSV52721346, COSV53165479; called by muse, varscan2
- AHI1 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99662595; called by muse, mutect2, varscan2
- AREL1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.037); catalogued as COSV100707598; called by muse, mutect2
- DNAJB11 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.679); catalogued as COSV99408616; called by muse, mutect2, varscan2
- EEF1G | c.413T>A p.I138N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100240340; called by muse, mutect2, varscan2
- FOXA2 | c.651C>G p.F217L (on ENST00000377115 / NM_153675.3; = p.F223L on NM_021784.5) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101008339, COSV65796015, COSV65797031; called by muse, mutect2, varscan2
- GOLGA2 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs138823741, COSV101425865; called by muse, mutect2, varscan2
- HOXA11 | c.837C>A p.N279K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766983697, COSV99135927; called by muse, mutect2, varscan2
- LHFPL2 | c.453G>C p.L151F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66713444; called by mutect2, varscan2
- MIGA2 | c.1118T>G p.F373C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99477581; called by muse, mutect2, varscan2
- NDUFA1 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101007031, COSV65097690; called by muse, mutect2, varscan2
- OR5K3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1404611741, COSV101051636; called by muse, mutect2, varscan2
- OXCT1 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV99542075; called by muse, mutect2, varscan2
- PAH | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs63329263, CD962117, CM068054, COSV100187990; ClinVar: uncertain significance / not provided; called by mutect2, varscan2
- PARN | c.657G>C p.W219C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.518); catalogued as COSV100420952; called by muse, mutect2, varscan2
- PITX2 | c.233A>T p.D78V (on ENST00000354925 / NM_001204397.1; = p.D85V on NM_000325.6) | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100146298; called by muse, mutect2
- PLXNB2 | c.3665G>C p.R1222T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834031; called by muse, mutect2, varscan2
- PTK2 | c.2984G>T p.G995V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100570084; called by muse, mutect2, varscan2
- RUSC2 | c.3179T>C p.I1060T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100770698; called by muse, mutect2, varscan2
- SERINC1 | c.392C>G p.A131G | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100305181; called by muse, mutect2
- SI | c.4921G>C p.E1641Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV100015307; called by muse, mutect2, varscan2
- SLITRK4 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62023555; called by muse, mutect2, varscan2
- SMG9 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99526713; called by muse, mutect2, varscan2
- SNX18 | c.1421T>G p.L474R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100410392; called by muse, mutect2
- ZNF609 | c.4153T>G p.Y1385D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100440924; called by muse, mutect2, varscan2
- EP300 | c.5258dup p.C1753Wfs*130 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- DMD | c.1173C>G p.A391= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1057522737, COSV99921897; called by muse, mutect2, varscan2
- DNAH5 | c.5682G>T p.V1894= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV54215354, COSV99449098; called by muse, mutect2, varscan2
- OR4A16 | c.126C>T p.L42= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100125187, COSV59042792; called by muse, mutect2, varscan2
- PGAM4 | c.81C>T p.D27= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs782463231, COSV100430694; called by muse, mutect2, varscan2
- THOC5 | c.168G>A p.K56= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100803565; called by muse, mutect2, varscan2
- THSD4 | c.1362G>C p.L454= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99965404; called by muse, mutect2
- TRIM5 | c.132G>A p.K44= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100000297; called by mutect2, varscan2
- YAP1 | c.933G>A p.L311= (on ENST00000282441 / NM_001130145.3; = p.L273= on NM_006106.5) | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs371123819; called by mutect2, varscan2
- MRPS17P9 | n.257T>G | RNA (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472322 T>G | 3'Flank (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
